Somatic mutation profile of tumor specimen TCGA-IE-A6BZ-01A (aliquot TCGA-IE-A6BZ-01A-11D-A307-09) from TCGA case TCGA-IE-A6BZ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 65.0 years (23,756 days).
Specimen TCGA-IE-A6BZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6b36826-ab77-4547-9054-fb0e8fe17c64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IE-A6BZ-10A (Blood Derived Normal), aliquot TCGA-IE-A6BZ-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fa4a938-82ca-4247-92c0-5bbe50aefae4

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 25, Silent 10, Nonsense Mutation 4, Splice Site 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.3173G>A p.R1058H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs776570997, COSV59201262; called by muse, mutect2, varscan2
- ADGRG4 | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV54953490, COSV54957702; called by muse, mutect2, varscan2
- CBX8 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as rs866445310, COSV99485868; called by muse, mutect2, varscan2
- CHD6 | c.6487-2A>G p.X2163_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100950977; called by muse, mutect2, varscan2
- COL16A1 | c.2443G>A p.G815S | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99594464; called by muse, mutect2
- COL4A2 | c.477C>T p.P159= | Splice Region (SNP) | VAF 56/178 reads (31%) | catalogued as rs534031166, COSV100847346, COSV100847542; called by muse, mutect2, varscan2
- CTNND1 | c.2773G>A p.D925N (on ENST00000399050 / NM_001085458.2; = p.D898N on NM_001331.3) | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as rs1204386527, COSV62382088; called by muse, mutect2
- CYP46A1 | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55894404; called by muse, mutect2, varscan2
- DMBT1 | c.2980A>T p.R994W (on ENST00000338354 / NM_001377530.1; = p.R495W on NM_004406.3) | Missense Mutation (SNP) | VAF 236/489 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100352923; called by muse, mutect2, varscan2
- FGD2 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780657307, COSV51464056; called by muse, mutect2, varscan2
- GTPBP1 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); catalogued as COSV99323201; called by muse, mutect2, varscan2
- KCNQ5 | c.2284A>G p.R762G | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as rs920695380, COSV100571962; called by muse, mutect2
- LMO7 | c.2659A>T p.K887* (on ENST00000357063; = p.K568* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 25/33 reads (76%) | catalogued as COSV100413151; called by muse, mutect2, varscan2
- MRPL15 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 163/355 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs756378155, COSV99477547; called by muse, mutect2, varscan2
- MYH2 | c.5443A>G p.K1815E | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99820102; called by muse, mutect2, varscan2
- NGRN | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 112/178 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs752093251, COSV58961237; called by muse, mutect2, varscan2
- NUP85 | c.1371T>A p.C457* | Nonsense Mutation (SNP) | VAF 63/88 reads (72%) | catalogued as COSV99822079; called by muse, mutect2, varscan2
- NUTM2F | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 51/636 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as COSV99480113; called by muse, mutect2
- PAPPA | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100074052; called by muse, mutect2, varscan2
- RAD54L2 | c.3039G>T p.L1013F | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.113); catalogued as COSV99621321; called by muse, mutect2
- ROR2 | c.622+1G>A p.X208_splice | Splice Site (SNP) | VAF 44/126 reads (35%) | catalogued as COSV65219594; called by muse, mutect2, varscan2
- SCNN1G | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as COSV100264183; called by muse, mutect2, varscan2
- SCRN3 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 57/61 reads (93%) | catalogued as rs757014041, COSV55807531; called by muse, mutect2, varscan2
- SMARCA2 | c.4003G>T p.E1335* | Nonsense Mutation (SNP) | VAF 61/241 reads (25%) | catalogued as rs1234359130, COSV100190418; called by muse, mutect2, varscan2
- TCOF1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs200375016, COSV60351834; called by muse, mutect2, varscan2
- TMEM35A | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as rs746305677, COSV54501890; called by muse, mutect2, varscan2
- TMEM63B | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV99441497; called by muse, mutect2, varscan2
- TMIGD1 | c.84T>A p.S28R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV100187227; called by muse, mutect2, varscan2
- TMPRSS11B | c.34T>G p.W12G | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100219372; called by muse, mutect2
- TRAPPC6B | c.267+2T>C p.X89_splice | Splice Site (SNP) | VAF 41/171 reads (24%) | catalogued as COSV100351227; called by muse, mutect2, varscan2
- TRHR | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1157358465, COSV100304841; called by muse, mutect2, varscan2
- ZNF221 | c.893A>G p.Q298R | Missense Mutation (SNP) | VAF 134/259 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV99240728; called by muse, mutect2, varscan2
- VPS13B | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2
- CEACAM21 | c.576G>A p.L192= | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as COSV99494501; called by muse, mutect2, varscan2
- HUWE1 | c.3093C>T p.D1031= | Silent (SNP) | VAF 43/666 reads (6%) | catalogued as COSV99472287; called by muse, mutect2
- MEP1A | c.204G>A p.L68= | Silent (SNP) | VAF 60/316 reads (19%) | catalogued as rs1442781075, COSV57921902; called by muse, mutect2, varscan2
- MPPED2 | c.270G>T p.L90= | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as COSV100813272; called by muse, mutect2
- PCDHA8 | c.2202G>A p.A734= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as rs200202372; called by muse, mutect2
- PCDHGC5 | c.2092C>T p.L698= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs1013118722, COSV99340058; called by muse, mutect2
- REG3G | c.378T>C p.D126= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as rs1180632920, COSV55449283, COSV99042311; called by muse, mutect2
- RTN1 | c.1641G>T p.T547= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs772649460, COSV99955422, COSV99955624; called by muse, mutect2, varscan2
- TRIO | c.2301G>T p.A767= | Silent (SNP) | VAF 87/172 reads (51%) | catalogued as COSV100710359, COSV60082734; called by muse, mutect2, varscan2
- ZCCHC12 | c.123A>T p.A41= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV100038503; called by muse, mutect2, varscan2
